TCGA case TCGA-78-7153 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Prince Charles Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c353f949-5f66-4a2c-b8f0-17be8bf19e0a

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Australia; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma with mixed subtypes: ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.8; Tissue or organ of origin: Overlapping lesion of lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 65.5 years (23,922 days); Year of diagnosis: 2003; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- ECOG performance status: 0; Timepoint: Preoperative.
- Follow-up contacts recording only the day: day 760, day 3,635.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 20; Tobacco smoking onset year: 1948; Tobacco smoking quit year: 1988.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-78-7153-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-78-7153-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-78-7153-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-78-7153-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-78-7153-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,635 days; disease-specific survival: no event (censored), 3,635 days; disease-free interval: no event (censored), 3,635 days; progression-free interval: no event (censored), 3,635 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-78-7153-01A-11D-2035-01): tumor purity 0.57, ploidy 4, whole-genome doublings 1.
